Somatic mutation profile of tumor specimen ER-ADXD-TTP1-A (aliquot ER-ADXD-TTP1-A-1-0-D-A595-35) from EXCEPTIONAL_RESPONDERS case ER-ADXD, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Overlapping lesion of colon; Age at diagnosis: 69.4 years (25,357 days).
Specimen ER-ADXD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 758b5352-7b38-4e96-b017-8597ddeabe8c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADXD-NT1-A (Solid Tissue Normal), aliquot ER-ADXD-NT1-A-1-0-D-A541-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c689eef5-208b-42d2-98a5-344fe4245f3d

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Del 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 245/602 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 149/398 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4192del p.S1398Vfs*17 | Frame Shift Del (DEL) | VAF 225/552 reads (41%) | catalogued as CD054298; called by mutect2, pindel, varscan2
- SMAD2 | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 148/412 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100054307, COSV50993184; called by muse, mutect2, varscan2
- SMAD4 | c.1619_1625del p.L540Pfs*10 | Frame Shift Del (DEL) | VAF 94/441 reads (21%) | called by mutect2, pindel, varscan2
- AR | c.411C>T p.A137= | Silent (SNP) | VAF 88/161 reads (55%) | catalogued as rs1308331665; called by muse, mutect2, varscan2
- KMT2A | c.4218+125T>C | Intron (SNP) | VAF 144/518 reads (28%) | called by muse, mutect2, varscan2
